Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6U2, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6U2-01A (Primary Tumor).

Histomorphology demonstrates oligodendroglial features. Single mitoses present.
Proliferation focally increased (up to 10%).

Diagnosis

Oligodendroglioma WHO grade II

ICD-O-3

Oligodendroglioma,
grade II J 9450/3

Oligodendroglioma NOS
9450/3

Site Brain, Supratentorial
NOS C71.0

QW 7/25/13

Untranslated original report
is housed at the BCR

Source: NCI Genomic Data Commons file ef162bf0-d52b-4fc3-a5cb-515ff8383ef6 (TCGA-S9-A6U2.C9E09216-EB85-433E-897C-874F3BBBC252.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).